Somatic mutation profile of tumor specimen 0DRZIV from CCDI case PBCGXI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.5 years (2,013 days).
Specimen 0DRZIV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7893bbef-2817-4afe-97f9-549c784d4e56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79a126da-16a3-4a9c-867b-e15e48525cdb

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 153/168 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TLR1 | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs751096819, COSV58304148; called by muse, varscan2
- CCM2L | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | called by muse, varscan2
- GAK | c.3818C>T p.A1273V | Missense Mutation (SNP) | VAF 101/280 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- ODF3L2 | c.128-3C>T | Splice Region (SNP) | VAF 62/110 reads (56%) | called by muse, varscan2
- POLN | c.2605T>G p.C869G | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, varscan2
- KLHDC7B | c.-10C>T | 5'UTR (SNP) | VAF 52/108 reads (48%) | catalogued as COSV67464994; called by muse, varscan2
- MGAT4D | c.-57G>T | 5'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
